Surgical pathology report (de-identified scan), TCGA case TCGA-YJ-A8SW, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Stanford University, specimen TCGA-YJ-A8SW-01A (Primary Tumor).

[page 1 of 4]
MRN:
DOB:
Adm:

Sex: M

Results: SURGICAL PROCEDURE (Order)

Status: Final result

Entry Date

Result Narrative

Accession No:

SPECIMEN SUBMITTED:

- A. LEFT PELVIC LYMPH NODE
- B. RIGHT PELVIC LYMPH NODES
- C. PROSTATE

ICD O-3

Adenocarcinoma, mucinous NOS 8484/3
Site: Prostate NOS C61.9
5/19/14

OPERATION: Prostatectomy.

CLINICAL DIAGNOSIS: Prostate cancer.

GROSS DESCRIPTION: Three specimens are received each labeled with the patient's name and medical record number.

The first specimen is additionally designated "left pelvic lymph node" and consists of a single fragment of fibrofatty tissue measuring 2.5 x 2.2 x 0.6 cm. The specimen is carefully searched revealing a single predominantly fatty, 2.2 cm lymph node which is bisected and entirely submitted in cassette A1.

The second specimen is received in formalin additionally designated "right pelvic lymph node" and consists of a single fragment of fibrofatty tissue measuring 3 x 1.5 x 0.5 cm. The specimen is carefully searched revealing a single predominantly fatty 2.5 cm lymph node which is bisected and entirely submitted in cassette B1.

The third specimen is received fresh from then OR additionally designated "prostate" and consists of a 79.9-gram, 5.9 x 4.5 x 4.4 cm prostatectomy specimen with an attached left seminal vesicle measuring 1.5 x 1 x 0.6 cm. There is a stump of the right seminal vesicle measuring 0.8 x 0.8 x 0.4 cm. The specimen is inked as follows: the anterior aspect is inked green, the left posterior aspect is inked blue, and the right posterior aspect is inked black. The apical and bladder neck margins are removed. The specimen is then serially sectioned from apex to base at 3 mm intervals revealing an asymmetrical prostate with the right lobe being larger than the left lobe. There is a firm, dense, suspicious nodule in the right posterior prostate measuring up to 2 cm in greatest dimension. The remaining prostate is somewhat rubbery and nodular with several cystic-like areas. Representative tissue is taken for research purposes by epresentative sections are submitted as follows: cassette C1 bladder neck margin en face, cassette C2 left apical margin serially sectioned, cassette C3 right apical margin serially sectioned, cassettes C4-C8 representative sections of left prostate from apex to base, cassettes C9-C13 representative sections of right prostate from apex to base (cassette C9 is corresponding half of prostate, cassette C4 etc.), cassette C14 section of left prostate and seminal vesicle, cassette

[page 2 of 4]
C15 representative section of left seminal vesicle, cassette C16
junction of right prostate seminal vesicle, cassette C17
representative sections of right seminal vesicle.

COMMENT: Histologic sections demonstrate high-grade prostatic adenocarcinoma, with a component of the tumor demonstrating mucinous features. The carcinoma demonstrates extensive perineural invasion, multifocal extraprostatic extension, and involvement of the surgical margin at the right posterior prostatic margin.

PROSTATE CARCINOMA SUMMARY

Site (left lobe, right lobe, bilateral) Bilateral
Specimen Type Radical prostatectomy
Size (cm) 2.2 x 1.7 cm (slide C13)
Volume (cubic cm) ~25% of total prostate volume
Gleason Grade (Score) 5+4=9
Gleason Grade 4/5 (%) >95%
Margin Status (specify site, extent) Involved, right posterior margin
Seminal Vesicle Involvement Yes, bilateral
Extracapsular Extension (specify site, extent) Yes, multifocal, right posterior prostate
Perineural Invasion Yes, extensive
Lymphovascular Invasion None identified
Large Venous Invasion None identified
Lymph Node Status, Left Uninvolved, (0/1)
Largest Metastatic Focus Not applicable
Extracapsular Extension Not applicable
Lymph Node Status, Right Uninvolved, (0/1)
Largest Metastatic Focus Not applicable
Extracapsular Extension Not applicable
TNM Stage pT3bR1 pN0 pMX

DIAGNOSIS:

LYMPH NODE, LEFT PELVIC, DISSECTION

-- NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1)

LYMPH NODE, RIGHT PELVIC, DISSECTION

-- NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1)

PROSTATE, RADICAL PROSTATECTOMY

-- HIGH-GRADE PROSTATIC ADENOCARCINOMA WITH FOCAL MUCINOUS
FEATURES, INVOLVING THE RIGHT POSTERIOR SURGICAL MARGIN (SEE COMMENT
AND SUMMARY TABLE ABOVE)

per TSS, mucinous = 20%

I have personally reviewed the specimen
and agree with the interpretation above.

Pathologist
Electronically signed

Components	Information
SURGICAL PROCEDURE (Order	

Provider Information

[page 3 of 4]
Authorizing Provider _____

Lab Information**Collection Information**

Collection Date _____

Collection Time _____

Order Details

Parent Order ID _____

Child Order ID _____

Lab IDs

Specimen # _____

Patient Release Status:

This result is not viewable by the patient.

Additional Information

Specimen ID _____

Bill Type _____

Client ID _____

Additional InformationSpecimen Date
Taken _____Specimen Time
Taken _____Specimen
Received Date _____Specimen
Received Time _____

Result Date _____

Result Time _____

MRN: _____

DOB: _____

Adm: _____

, Sex: M

Order**SURGICAL PROCEDURE****(Order****Patient Information**

Patient Name _____

MRN _____

Sex
Male

DOB _____

SSN _____

Unit _____

Room _____

Bed _____

Provider Information

Ordering User _____

Authorizing Provider _____

Results, _____

Attending Provider(s) _____

Admitting Provider _____

Order Details

Frequency _____

Priority _____

Order Class _____

[page 4 of 4]
ONCE

Routine

Clinic Collect

Order Information

Order Date/Time

Physician Start Date/Time

Account Information

Account #

Collection Information

Collected By: _____

Collect Date: _____

Collect Time: _____

inted by

Source: NCI Genomic Data Commons file 415f7845-b2aa-4084-adf0-ff4f3a95057a (TCGA-YJ-A8SW.33D6587B-0289-49B5-9D16-497B6C17EFD9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).